Gene-level copy-number profile of tumor specimen TCGA-DD-A3A7-01A from TCGA case TCGA-DD-A3A7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 67.3 years (24,599 days).
Specimen TCGA-DD-A3A7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.236a53ec-015d-4cb7-bdbd-2a3f0174ac20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A3A7-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccd90ab8-db3b-4dce-989e-d7fc65870eaa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,201; copy number 2: 32,875; copy number 3: 6,437; copy number 4: 9,304; copy number 5: 3,284; copy number 6: 664; copy number 7: 22; copy number 8: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A3A7-01A-11D-A22E-01): tumor purity 0.82, ploidy 2.57, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,000 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–247,761,255, 2,536 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:248,197,265–248,919,946, 40 genes, copy number 5: OR2M3, OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:172,735,274–173,431,812, 8 genes, copy number 6: RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1.
- chr2:187,712,816–214,410,501, 425 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:174,336,295–174,730,896, 6 genes, copy number 5 (within-gene range 4–5): LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2.
- chr5:174,751,734–174,751,787, 1 gene, copy number 5: MIR4634.
- chr8:94,791,643–145,066,685, 803 genes, copy number 5–6 (broad region; genes not listed).
- chr9:3,824,127–4,348,392, 1 gene, copy number 5 (within-gene range 3–5): GLIS3.
- chr9:4,070,906–4,782,078, 13 genes, copy number 5: AL359095.1, AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1.
- chr19:31,797,666–35,813,299, 167 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,780. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
